Somatic mutation profile of tumor specimen 0DTB8Y from CCDI case PBCJNH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Malignant tumor, spindle cell type; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.6 years (6,423 days).
Specimen 0DTB8Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ec14b94-9160-491a-88a0-61f397332053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a068e99-2002-47b0-8ae6-f69020faf47c

The open-access MAF lists 58 somatic variants for this specimen: 30 protein-altering or splice-affecting, 17 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 17, Intron 8, Nonsense Mutation 2, Frame Shift Del 2, 5'UTR 2, In Frame Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 424/540 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2A3 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 139/1236 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV59235117; called by muse, mutect2, varscan2
- CHRM3 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 16/536 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55081470; called by muse, mutect2
- DICER1 | c.5114A>T p.E1705V | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58616864, COSV58619272; called by muse, mutect2, varscan2
- GALNT7 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 30/304 reads (10%) | catalogued as rs1211486263, COSV53928615; called by muse, mutect2, varscan2
- HDX | c.787C>G p.R263G | Missense Mutation (SNP) | VAF 204/328 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV52981594; called by muse, mutect2, varscan2
- NKX2-8 | c.398A>T p.Q133L | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566632187; called by muse, mutect2, varscan2
- NRK | c.2617G>C p.D873H | Missense Mutation (SNP) | VAF 103/502 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs779292616; called by muse, mutect2, varscan2
- SLITRK4 | c.1388A>G p.E463G | Missense Mutation (SNP) | VAF 108/359 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62024902; called by muse, mutect2, varscan2
- TNRC6A | c.5371C>T p.Q1791* | Nonsense Mutation (SNP) | VAF 116/450 reads (26%) | catalogued as COSV59370905; called by muse, mutect2, varscan2
- ANO3 | c.2075G>C p.C692S | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AUTS2 | c.3173G>A p.G1058E | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.143); called by muse, mutect2
- CROT | c.317C>G p.P106R | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CTTNBP2 | c.3677C>G p.T1226S | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.364); called by muse, mutect2
- FAM214A | c.1877G>A p.S626N | Missense Mutation (SNP) | VAF 31/425 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.033); called by muse, mutect2
- FCER2 | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 142/481 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNH5 | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MTCL1 | c.2681A>G p.N894S (on ENST00000306329 / NM_001378206.1; = p.N534S on NM_015210.4) | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NCCRP1 | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NDST3 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- OSGIN2 | c.546_550del p.Y182* | Frame Shift Del (DEL) | VAF 61/278 reads (22%) | called by mutect2, pindel, varscan2
- PDGFRB | c.1678_1689del p.P560_E563del | In Frame Del (DEL) | VAF 192/335 reads (57%) | called by mutect2, pindel, varscan2
- RASGRP3 | c.878A>C p.D293A | Missense Mutation (SNP) | VAF 90/588 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RNF213 | c.10219G>A p.E3407K | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SAMD13 | c.218A>T p.Q73L (on ENST00000370671; = p.Q67L on NM_001010971.3) | Missense Mutation (SNP) | VAF 262/443 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SART3 | c.1117G>A p.D373N (on ENST00000228284; = p.D355N on NM_014706.4) | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SLC13A1 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.769); called by muse, mutect2
- ZNF219 | c.1119del p.E374Sfs*9 | Frame Shift Del (DEL) | VAF 93/232 reads (40%) | called by mutect2, pindel*, varscan2
- ZNF335 | c.2195T>C p.L732P | Missense Mutation (SNP) | VAF 109/493 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF34 | c.97-4C>G | Splice Region (SNP) | VAF 26/635 reads (4%) | called by muse, mutect2
- ANO3 | c.2076C>T p.C692= | Silent (SNP) | VAF 80/293 reads (27%) | called by muse, mutect2, varscan2
- CEBPB | c.978C>G p.T326= | Silent (SNP) | VAF 317/467 reads (68%) | catalogued as rs1171656066; called by muse, mutect2, varscan2
- CISH | c.546G>T p.P182= (on ENST00000348721 / NM_145071.4; = p.P199= on NM_013324.6) | Silent (SNP) | VAF 108/333 reads (32%) | catalogued as rs78700237; called by muse, mutect2, varscan2
- CYP4A11 | c.399G>C p.L133= | Silent (SNP) | VAF 59/326 reads (18%) | called by muse, mutect2, varscan2
- FLG2 | c.2472G>T p.G824= | Silent (SNP) | VAF 180/767 reads (23%) | catalogued as rs774329489; called by muse, mutect2, varscan2
- OR5H14 | c.117C>T p.I39= | Silent (SNP) | VAF 117/482 reads (24%) | catalogued as COSV71194002; called by muse, mutect2, varscan2
- PCDH19 | c.3285G>A p.E1095= (on ENST00000373034 / NM_001184880.2; = p.E1047= on NM_020766.3) | Silent (SNP) | VAF 23/566 reads (4%) | called by muse, mutect2
- PCDHA3 | c.1824G>T p.S608= | Silent (SNP) | VAF 76/378 reads (20%) | catalogued as COSV63539171; called by muse, mutect2, varscan2
- PIGT | c.714G>A p.L238= | Silent (SNP) | VAF 138/570 reads (24%) | catalogued as rs1355289635, COSV54125822; called by muse, mutect2, varscan2
- RADX | c.87C>T p.V29= | Silent (SNP) | VAF 125/670 reads (19%) | called by muse, mutect2, varscan2
- RADX | c.291G>A p.V97= | Silent (SNP) | VAF 143/747 reads (19%) | catalogued as rs1399754669; called by muse, mutect2, varscan2
- RBSN | c.52C>T p.L18= | Silent (SNP) | VAF 138/417 reads (33%) | catalogued as COSV53795554; called by muse, mutect2, varscan2
- SATB1 | c.840G>A p.E280= | Silent (SNP) | VAF 75/356 reads (21%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2613C>T p.I871= | Silent (SNP) | VAF 59/233 reads (25%) | catalogued as COSV55909455; called by muse, mutect2, varscan2
- SYT16 | c.297G>A p.Q99= | Silent (SNP) | VAF 99/495 reads (20%) | called by muse, mutect2, varscan2
- USP15 | c.1368A>G p.V456= (on ENST00000280377 / NM_001351159.2; = p.V427= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 123/471 reads (26%) | called by muse, mutect2, varscan2
- ZNF316 | c.1320C>T p.R440= | Silent (SNP) | VAF 21/421 reads (5%) | catalogued as rs940425545; called by muse, mutect2
- ARHGAP44 | c.1523+86C>T | Intron (SNP) | VAF 15/102 reads (15%) | catalogued as rs1004541434; called by muse, mutect2
- EPB42 | c.1618+89del | Intron (DEL) | VAF 8/54 reads (15%) | called by pindel, varscan2
- LAMA5 | c.9504+34C>A | Intron (SNP) | VAF 125/416 reads (30%) | catalogued as rs369564825; called by muse, mutect2, varscan2
- MS4A6A | c.-159C>A | 5'UTR (SNP) | VAF 64/404 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.22786+37C>G | Intron (SNP) | VAF 43/194 reads (22%) | called by muse, mutect2, varscan2
- PHF12 | c.-63T>A | 5'UTR (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- PKP4 | c.2094-90G>A | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2
- SPG7 | c.1759-43C>T | Intron (SNP) | VAF 16/89 reads (18%) | catalogued as rs769706707; called by muse, mutect2, varscan2
- SRD5A1 | c.294-6681G>A | Intron (SNP) | VAF 29/150 reads (19%) | catalogued as rs1018052824; called by muse, mutect2, varscan2
- TPK1 | c.501+22T>A | Intron (SNP) | VAF 51/236 reads (22%) | called by muse, mutect2, varscan2
- ZNF879 | c.*2A>G | 3'UTR (SNP) | VAF 51/313 reads (16%) | catalogued as rs774887444; called by muse, mutect2, varscan2
